Surgical pathology report (de-identified scan), TCGA case TCGA-FD-A6TC, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site BLN - University Of Chicago, specimen TCGA-FD-A6TC-01A (Primary Tumor).

[page 1 of 4]
Sample #

Gender: Female

DOB:

Race: White

Report Date:

Pathology Report:

PD0-3
Carcinoma, urothelial NOS
8/20/13
Site: Posterior wall of
bladder C67.4
JSD 7/22/13

Surgical Pathology Report

FINAL PATHOLOGIC DIAGNOSIS

A. Urinary bladder; radical cystectomy, anterior vaginectomy and right salphingo-oophorectomy:

- Bladder with invasive high-grade urothelial carcinoma, invading through the muscularis propria, and into the perivesicular fat and vaginal wall, see pathologic parameters.
- Urothelial carcinoma in-situ involving bladder dome and posterior wall mucosa.
- Ovary with age-related changes.
- Fallopian tube, no tumor.
- Margins, free of tumor.

B. Right pelvic lymph nodes; dissection:

- Eight lymph nodes, no tumor (0/8).

C. Left pelvic lymph nodes; dissection:

- Eight lymph nodes, no tumor (0/8).

D. Left distal urethral margin; excision:

- Portion of ureter, no tumor.

E. Right distal ureter; excision:

- Portion of ureter, no tumor.

Urothelial Carcinoma Pathologic Parameters

1. Tumor type: Invasive urothelial carcinoma.
2. Grade of tumor: High grade.
3. Depth of invasion: Adjacent organ: Vaginal wall.
4. Tumor distribution: Solitary, 2.5 cm, posterior bladder wall extending to perivesical fat and vaginal wall.
5. Ureteral margins: Negative for tumor.
6. Distal urethral margin: Negative for tumor.

[page 2 of 4]
7. Soft tissue margin or serosa: Negative for tumor.
8. Lymph nodes: Negative for tumor (0/16).
9. pTNM: pT4a,N0,MX

Effective January 1, 2010 this Checklist utilizes the 7th edition TNM staging system for Bladder of the American Joint Committee on Cancer (AJCC) and the International Union Against Cancer (UICC).

Interpretation performed by the Attending Pathologist and reviewed with the Resident/Fellow, [], MD, PhD
Electronically Signed Out by [] MD

Clinical History:

Patient is a year-old female clinical history of bladder cancer who undergoes cystectomy, ileo conduit N. retroperitoneal lymph node dissection.

Specimens Received:

- A: Bladder
- B: Right pelvic lymph nodes
- C: Left pelvic lymph nodes
- D: Left distal urethral margin
- E: Right distal ureter

Gross Description:

The specimens are received in five containers each labeled with the patient's name and medical record number.

A. The first container is additionally identified as, "bladder". Received fresh and place in formalin is a 145.08 g cystectomy specimen with overall measurements of 12.5 x 11.0 x 3.7 cm. The right ureteral stump measures 3 cm in length and 0.4 cm in diameter, and the left measures 2.5 cm in length and 0.7 cm in diameter, and both demonstrate intact patent lumens. The serosal surface shows yellow, lobulated fibroadipose tissue with focal cautery artifact. There is a 2.5 x 2.0 x 1.5 cm matted area on left posterior bladder held together by a suture which is removed to reveal a 1.6 x 0.9 cm defect and a 4.0 x 3.5 cm area of peritoneal discoloration on the right side adjacent to the dome. There is a 7.4 x 7.0 cm portion of tan-pink vaginal mucosa fixed on the posterior aspect of the bladder. The urethral margin is inked black, and the bladder is inked blue on the right half and black on the left half. The bladder measures 6.0 x 5.5 x 2.5 cm. The specimen is opened anteriorly to reveal a 2.5 x 1.7 cm red-tan, hemorrhagic, friable, ulceration located in posterior wall within an ill-defined

[page 3 of 4]
4.1 x 3 cm area of induration. On cut section, the mass is white-tan, indurated, and extends through the muscularis propria and pericystic adipose tissue and abuts the deep surgical margin (i.e. 2.5 cm of 2.6 cm of the total thickness of the specimen). Inferiorly, the induration also appears to abut the vaginal wall. The surrounding bladder mucosa is wrinkled, congested, pink-tan with a uniform 0.5-0.9 cm wall thickness. Bilateral ureteral orifices, adjacent to the trigone, are identified and probe patent.

Representative sections are submitted as follows:

- A1: Left ureter
- A2: Right ureter
- A3: Urethral margin
- A4: Uninvolved bladder mucosa anterior wall
- A5: Uninvolved bladder mucosa posterior wall
- A6: Uninvolved bladder mucosa bladder dome
- A7-A10: Bladder mass/Ulceration
- A11-A13: Bladder mass abutting the vaginal wall
- A14 Fallopian tube
- A15-A16 Ovary

B. The second container is additionally identified as, "right pelvic lymph nodes". Received fresh and placed in formalin is a 5.0 x 4.5 x 0.9 cm aggregate of soft, rubbery, yellow-tan tissue fragments that are dissected for approximately 10 lymph node candidates are submitted as follows

- B1: Two lymph node candidates
- B2: One lymph node candidates, bisected
- B3 B4: One lymph node candidates, bisected, one half in each cassette
- B5: Five lymph node candidates
- B6: One lymph node candidates, bisected

C. The third container is additionally identified as, "left pelvic lymph nodes". Received fresh and placed in formalin is a 4.0 x 3.5 x 1.1 cm aggregate of soft, rubbery, yellow-tan tissue fragments that are dissected for approximately 9 lymph node candidates are submitted as follows

- C1: Five lymph node candidates
- C2: One lymph node candidates, bisected
- C3: One lymph node candidates
- C4: One lymph node candidates, bisected
- C5-C6: One lymph node candidates, bisected, one half in each cassette

D. The fourth container is additionally identified as, "left distal ureteral margin stitch on margin side ". Received in formalin is a 2.3 cm in length by 0.9 cm in external diameter segment of ureter. There is a stitch on the non-margin side. The serosal surface of the margin side is inked black. The margin side of the ureter and a representative section are submitted in cassette D1.

[page 4 of 4]
E. The fifth container is additionally identified as, "right distal ureter, stitch on margin side". Received in formalin is a 2.9 cm in length by 0.5 cm in external diameter segment of ureter. The non-margin side is indicated with a suture. The margin side is inked black and is submitted with a representative section of the ureter in cassette E1.

APAA Discrepancy		✓
Prior Malignancy History	breast - no	✓

Source: NCI Genomic Data Commons file ded29231-9a25-4427-a9b8-ab9e3fc4c0ce (TCGA-FD-A6TC.035F00F9-9B4B-4628-829B-D4C1E3219C90.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).